CCDI case PBBUDU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/d7575b9e-eda6-445f-b912-0cb6c5a25c2b

Demographics
Sex at birth: female.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Mediastinum, NOS; Age at diagnosis: 14.0 years (5,111 days).

Biospecimens (3 samples)
- Sample 0DI1JN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI1V0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI1ZC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
